Somatic mutation profile of tumor specimen TCGA-66-2727-01A (aliquot TCGA-66-2727-01A-01D-0983-08) from TCGA case TCGA-66-2727, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 55.2 years (20,150 days).
Specimen TCGA-66-2727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e854561-40e8-48b4-a78d-afb5cbb8c667.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2727-11A (Solid Tissue Normal), aliquot TCGA-66-2727-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12238ed3-e05a-4c37-b94f-d1b043c18019

The open-access MAF lists 228 somatic variants for this specimen: 167 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 55, Nonsense Mutation 13, Frame Shift Del 9, RNA 3, Intron 3, In Frame Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 25/39 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TYR | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as rs62645917, CM941348, CM942074, COSV54475871; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCE1 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV56848500; called by muse, mutect2, varscan2
- ABCG8 | c.1858C>A p.L620I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs746858868, COSV55394916, COSV55395571; called by muse, mutect2, varscan2
- AC139530.2 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV61269731; called by muse, mutect2, varscan2
- ACSM5 | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59373784; called by muse, mutect2, varscan2
- ACSS3 | c.1560G>T p.Q520H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV54098532; called by muse, mutect2, varscan2
- ADAM18 | c.1034A>T p.N345I | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55852517; called by muse, mutect2, varscan2
- ADAMTS15 | c.2161G>T p.G721W | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54508433, COSV54508690; called by muse, mutect2, varscan2
- ADGRG4 | c.9194G>T p.S3065I | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as COSV54963849; called by muse, mutect2, varscan2
- AFAP1L2 | c.1866C>G p.I622M | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV58417686; called by muse, mutect2, varscan2
- AGTPBP1 | c.3163A>T p.R1055W (on ENST00000357081 / NM_001330701.2; = p.R1015W on NM_015239.2) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61275770; called by muse, mutect2, varscan2
- AGTR1 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.088); catalogued as COSV62559646; called by muse, mutect2, varscan2
- AHNAK | c.13477G>A p.V4493I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.122); catalogued as rs771080738, COSV57224692, COSV57225319; called by muse, mutect2, varscan2
- AK7 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV50878974; called by muse, mutect2, varscan2
- ANK3 | c.5428G>T p.A1810S | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as COSV55074886; called by muse, mutect2, varscan2
- ANKRD30A | c.3883A>G p.M1295V (on ENST00000611781; = p.M1239V on NM_052997.2) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV64617458; called by muse, mutect2, varscan2
- APC | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as CD033949, COSV57332659, COSV57339569, COSV57369499; called by muse, mutect2, varscan2
- AR | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.248); catalogued as COSV65962155; called by muse, mutect2, varscan2
- ASXL2 | c.4082C>T p.S1361L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55465061; called by muse, mutect2, varscan2
- ATP13A3 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55468326; called by muse, mutect2
- ATRN | c.3475C>G p.L1159V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV53532280; called by muse, varscan2
- BDP1 | c.6659A>T p.D2220V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV62430635; called by muse, mutect2, varscan2
- BICC1 | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV65863559; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2899G>A p.A967T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs775996769, COSV63245635; called by mutect2, varscan2
- BNIP5 | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as COSV71325779; called by muse, mutect2, varscan2
- BUB1B | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748512524, COSV55015561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C9orf85 | c.85A>T p.K29* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV58255618; called by muse, mutect2, varscan2
- CACNA2D2 | c.3116C>T p.S1039F (on ENST00000479441 / NM_001174051.3; = p.S1032F on NM_006030.4) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765799361, COSV56567654; called by muse, mutect2
- CAMSAP2 | c.3967_3969del p.C1323del (on ENST00000236925 / NM_001297707.2; = p.C1312del on NM_203459.3) | In Frame Del (DEL) | VAF 21/208 reads (10%) | catalogued as rs763549843; called by mutect2, pindel, varscan2
- CBLL2 | c.441C>A p.S147R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV60369915; called by muse, mutect2, varscan2
- CDK2AP2 | c.179A>T p.Q60L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV56874300; called by muse, mutect2, varscan2
- CDKAL1 | c.767C>G p.T256S | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.823); catalogued as COSV51188508; called by muse, mutect2, varscan2
- CFAP54 | c.7945G>T p.G2649* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV61572419, COSV61574250; called by muse, mutect2, varscan2
- CFH | c.1660G>A p.G554S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.641); catalogued as COSV66410662; called by muse, mutect2, varscan2
- CFHR5 | c.970+1G>C p.X324_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV56826351; called by muse, mutect2, varscan2
- CLCN5 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV56586033; called by muse, mutect2, varscan2
- CXorf21 | c.827T>C p.L276S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66763147; called by muse, mutect2, varscan2
- CXorf66 | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV65169631; called by muse, mutect2, varscan2
- CYLC1 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV61414871; called by muse, mutect2, varscan2
- CYSLTR1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV64820996; called by muse, mutect2, varscan2
- DCAF8L1 | c.1654G>T p.V552L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs770928929, COSV71595462, COSV71595570; called by muse, mutect2, varscan2
- DDX60L | c.2393A>T p.K798M | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52719555; called by muse, mutect2, varscan2
- DIDO1 | c.5546A>T p.H1849L | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV56631214; called by muse, mutect2, varscan2
- EFCAB13 | c.837A>G p.I279M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs908879630, COSV58951469; called by muse, mutect2, varscan2
- EFHC2 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV69555018; called by muse, mutect2, varscan2
- ELK4 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV56985912; called by muse, mutect2, varscan2
- EPHB2 | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65865244; called by muse, mutect2, varscan2
- ESF1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV52523344; called by muse, mutect2, varscan2
- ESX1 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV65424955, COSV65425199; called by muse, mutect2, varscan2
- EVC2 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60392634, COSV60399802; called by muse, mutect2, varscan2
- EXO1 | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV62219089; called by muse, mutect2, varscan2
- FNTA | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV56491240; called by muse, mutect2, varscan2
- FOLH1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV57054518; called by mutect2, varscan2
- FUT9 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.104); catalogued as COSV56153652; called by muse, varscan2
- GPRASP1 | c.3794C>A p.T1265N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64356247; called by muse, mutect2, varscan2
- GTF3C1 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV62243941; called by muse, mutect2, varscan2
- HHIP | c.1830G>T p.R610S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56842908; called by muse, mutect2, varscan2
- HIBADH | c.554C>A p.A185D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55316030; called by muse, mutect2, varscan2
- INSL3 | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57953725; called by mutect2, varscan2
- ITGB3 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as rs779974422, COSV71384975; called by mutect2, varscan2
- ITGB4 | c.2598G>T p.Q866H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52330940; called by muse, mutect2, varscan2
- IVNS1ABP | c.341T>C p.M114T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV62250240; called by muse, mutect2, varscan2
- KBTBD6 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101068881, COSV65271802; called by muse, mutect2, varscan2
- KCTD4 | c.243G>C p.R81S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV61242064; called by muse, mutect2, varscan2
- KDM3B | c.4583C>G p.P1528R | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58693849; called by muse, mutect2, varscan2
- KIDINS220 | c.4949A>G p.K1650R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56757628; called by muse, mutect2, varscan2
- KNDC1 | c.4640G>T p.W1547L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58843779; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1123G>T p.V375L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV59974208, COSV59981818; called by muse, mutect2, varscan2
- KSR2 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as COSV60389945; called by muse, mutect2, varscan2
- LAMA3 | c.3458G>T p.R1153L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58069165, COSV58076109; called by muse, varscan2
- LAMA4 | c.3879G>A p.M1293I (on ENST00000230538 / NM_001105206.3; = p.M1286I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1554329600, COSV57898237, COSV57905568; called by muse, mutect2, varscan2
- LAMB4 | c.4129G>C p.G1377R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52720839, COSV52727511; called by muse, mutect2, varscan2
- LEPR | c.3257A>G p.K1086R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as COSV62750714; called by muse, mutect2, varscan2
- LEPROT | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.956); catalogued as COSV60761218; called by muse, mutect2, varscan2
- LHFPL3 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV67817696; called by mutect2, varscan2
- LILRB5 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); catalogued as COSV60260106; called by muse, mutect2, varscan2
- LRG1 | c.475T>G p.W159G | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV56705493; called by muse, mutect2, varscan2
- LRIT2 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60565398; called by muse, mutect2, varscan2
- LYZL1 | c.567dup p.G190Rfs*3 (on ENST00000375500; = p.G144Rfs*3 on NM_032517.6) | Frame Shift Ins (INS) | VAF 49/197 reads (25%) | catalogued as rs1376851399; called by pindel, varscan2
- MAGEC3 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV71610159; called by muse, mutect2, varscan2
- MBD5 | c.3463G>T p.D1155Y | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV68698568; called by muse, mutect2, varscan2
- MCF2 | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs776605373, COSV58492281; called by muse, mutect2, varscan2
- MCHR1 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV50762422; called by muse, mutect2, varscan2
- MFAP5 | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.876); catalogued as COSV63946045; called by muse, mutect2, varscan2
- MSN | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV64303547; called by mutect2, varscan2
- MTF1 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100888641, COSV65990187; called by muse, mutect2, varscan2
- MUC16 | c.36845G>T p.C12282F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67484034; called by muse, mutect2, varscan2
- MUC6 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV70147794; called by muse, mutect2, varscan2
- NDUFB5 | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52021255, COSV52021412; called by muse, mutect2, varscan2
- NDUFS1 | c.959A>T p.E320V | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV51912593; called by muse, mutect2, varscan2
- NR4A2 | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59894582; called by muse, mutect2, varscan2
- OFD1 | c.1223T>A p.L408H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60798003; called by muse, mutect2
- OR10X1 | c.767C>G p.T256S | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV63767781, COSV63767822; called by muse, mutect2, varscan2
- OR2A25 | c.442T>C p.W148R | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007292864, COSV68717541; called by muse, mutect2, varscan2
- OR52J3 | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV66746357, COSV66747598; called by muse, mutect2, varscan2
- OR52K2 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs762408844, COSV57835654; called by muse, mutect2, varscan2
- OR5M3 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56568082; called by muse, mutect2, varscan2
- OR6F1 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57469054; called by muse, mutect2, varscan2
- OR8U1 | c.10A>C p.I4L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100163879; called by muse, varscan2
- OTUD7B | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV64917415; called by muse, mutect2, varscan2
- PABPC5 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57042639; called by muse, mutect2, varscan2
- PAGE1 | c.48T>A p.Y16* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV65998514; called by muse, mutect2, varscan2
- PCDH10 | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.938); catalogued as rs773032336, COSV52101121; called by muse, mutect2, varscan2
- PCDHB5 | c.1834G>T p.G612W | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99167843; called by mutect2, varscan2
- PCDHGA5 | c.951G>T p.M317I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.013); catalogued as rs752099096, COSV54006047, COSV54033579; called by muse, mutect2, varscan2
- PCDHGA6 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.103); catalogued as COSV54006058; called by muse, mutect2, varscan2
- PCSK6 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59343759; called by muse, mutect2, varscan2
- PFKL | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100827103, COSV62464975; called by muse, mutect2, varscan2
- PIK3CB | c.111del p.T38Lfs*46 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as COSV100006029; called by mutect2, pindel, varscan2
- PLCG1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV54822406; called by muse, mutect2, varscan2
- POU6F2 | c.1026G>T p.Q342H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68879815; called by muse, mutect2, varscan2
- PPFIA2 | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61047709, COSV61051369; called by muse, mutect2, varscan2
- PRB1 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as COSV53705859; called by muse, mutect2, varscan2
- PRLR | c.138C>A p.C46* | Nonsense Mutation (SNP) | VAF 52/117 reads (44%) | catalogued as COSV51498934; called by muse, mutect2, varscan2
- PRUNE2 | c.2054C>G p.S685* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV65045792, COSV65047559; called by muse, mutect2, varscan2
- PSTPIP1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs372468528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRO | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV55519258; called by muse, varscan2
- PZP | c.4034C>A p.S1345Y | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV54367636; called by muse, mutect2, varscan2
- RABL3 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs781463272, COSV56337437; called by mutect2, varscan2
- RASSF9 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 56/116 reads (48%) | catalogued as COSV100771311, COSV63435387; called by muse, varscan2
- RBL2 | c.3329G>A p.S1110N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs771503071, COSV50884588; called by muse, mutect2, varscan2
- RIMBP2 | c.2668G>T p.D890Y | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55480717, COSV55482777; called by muse, mutect2, varscan2
- RPAP2 | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV72101634; called by muse, mutect2, varscan2
- RPGR | c.2475G>C p.K825N (on ENST00000339363 / NM_001367249.1; = p.K620N on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV58838702; called by muse, mutect2, varscan2
- RPS26 | c.123T>G p.I41M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56270596; called by muse, mutect2, varscan2
- SCAPER | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57749525; called by muse, mutect2, varscan2
- SCN1A | c.2204C>T p.P735L (on ENST00000303395 / NM_001202435.3; = p.P724L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV57682028; called by muse, mutect2, varscan2
- SI | c.5089G>T p.A1697S | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV52294156; called by muse, mutect2, varscan2
- SLC5A1 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV56688114; called by muse, mutect2, varscan2
- SLC6A14 | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64148166; called by muse, mutect2, varscan2
- SLITRK4 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV62025585; called by muse, mutect2, varscan2
- TBC1D8B | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52182245; called by muse, mutect2, varscan2
- TBX20 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68785154; called by muse, mutect2, varscan2
- TCEAL3 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.41); catalogued as COSV54581248, COSV99685192; called by muse, mutect2, varscan2
- TDO2 | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV72233044; called by muse, mutect2, varscan2
- THOC2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55553226; called by muse, mutect2, varscan2
- TLN1 | c.1354A>G p.I452V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1224311715, COSV59210597; called by muse, mutect2, varscan2
- TMEM230 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV52532111, COSV52533028; called by muse, mutect2, varscan2
- TTC9B | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV53424522; called by muse, mutect2, varscan2
- TTN | c.7936C>T p.P2646S (on ENST00000591111; = p.P2600S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | PolyPhen possibly damaging (0.859); catalogued as COSV100616675, COSV60258500; called by muse, mutect2, varscan2
- UNC13C | c.812A>G p.K271R | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs774162675, COSV52909407; called by muse, mutect2, varscan2
- UPF3B | c.862G>T p.E288* (on ENST00000276201 / NM_080632.3; = p.E275* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 45/146 reads (31%) | catalogued as COSV52231123; called by muse, varscan2
- UPF3B | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV52231129; called by muse, varscan2
- WT1 | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV60079136; called by muse, mutect2, varscan2
- XIRP2 | c.4706A>T p.Q1569L (on ENST00000628543; = p.Q1744L on NM_152381.6) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV54724808; called by muse, mutect2, varscan2
- XIRP2 | c.7630G>C p.D2544H (on ENST00000628543; = p.D2719H on NM_152381.6) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV54724818; called by muse, mutect2, varscan2
- ZFHX4 | c.2339G>C p.R780T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV51486199; called by muse, mutect2, varscan2
- ZNF14 | c.928A>G p.K310E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV59850839; called by muse, mutect2, varscan2
- ZNF208 | c.3194C>A p.A1065D | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs772202565, COSV68100243; called by muse, mutect2, varscan2
- ZNF431 | c.1606A>G p.R536G | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60674750; called by muse, mutect2, varscan2
- ZNF611 | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.569); catalogued as COSV60542681; called by muse, mutect2, varscan2
- ZNF630 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52097772, COSV99332547; called by muse, mutect2, varscan2
- ZNF75D | c.1088A>T p.K363I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66133272; called by muse, mutect2, varscan2
- AADACL4 | c.1093del p.V365Sfs*3 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- E2F7 | c.224_230del p.R75Kfs*11 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- IGKV1-9 | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGKV2-24 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- IPO9 | c.645del p.F215Lfs*7 | Frame Shift Del (DEL) | VAF 38/142 reads (27%) | called by mutect2, varscan2
- MS4A3 | c.156+1del | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RB1 | c.1351_1357delinsA p.R451_Y453delinsN | In Frame Del (DEL) | VAF 10/23 reads (43%) | called by pindel, varscan2*
- RBM14 | c.1247del p.P416Hfs*56 | Frame Shift Del (DEL) | VAF 37/150 reads (25%) | called by mutect2, pindel, varscan2
- SV2C | c.111_112delinsG p.Q38Rfs*62 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | called by pindel, varscan2*
- TMEM63B | c.1757del p.L586Rfs*10 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel
- TRGV5 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZNF318 | c.3253_3254del p.M1085Afs*3 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by pindel, varscan2
- ABCB5 | c.408C>A p.T136= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs374303845, COSV51717373; called by mutect2, varscan2
- ABI3BP | c.801G>C p.L267= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV52531513, COSV52546932; called by muse, mutect2, varscan2
- ACACA | c.3234C>T p.V1078= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs768329159; called by muse, mutect2, varscan2
- AFF2 | c.735C>A p.A245= | Silent (SNP) | VAF 31/208 reads (15%) | catalogued as rs782663982, COSV100649822, COSV60682910; called by muse, mutect2, varscan2
- AKT2 | c.510G>T p.R170= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV60909836; called by muse, mutect2, varscan2
- BFSP1 | c.612G>T p.T204= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV64901447; called by muse, mutect2, varscan2
- BTK | c.42C>A p.S14= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV58122758; called by muse, mutect2, varscan2
- C14orf28 | c.111T>G p.A37= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV57333999; called by muse, mutect2, varscan2
- CADPS | c.1992C>T p.G664= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1411411120, COSV51895752; called by muse, mutect2, varscan2
- CCDC160 | c.939A>T p.S313= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV66251881; called by muse, mutect2
- CEACAM16 | c.453T>A p.L151= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV69188019; called by muse, mutect2, varscan2
- CLIC6 | c.1455A>T p.G485= (on ENST00000360731 / NM_001317009.2; = p.G467= on NM_053277.3) | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV62448890; called by muse, mutect2, varscan2
- CNTNAP5 | c.2427G>T p.A809= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV101443531, COSV70504316; called by muse, mutect2, varscan2
- DMXL1 | c.3387A>G p.K1129= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV60718824; called by muse, mutect2, varscan2
- DOCK1 | c.5160C>T p.S1720= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV54753992; called by muse, mutect2, varscan2
- EEFSEC | c.450C>G p.L150= | Silent (SNP) | VAF 95/378 reads (25%) | catalogued as COSV54626228; called by muse, mutect2, varscan2
- GPR101 | c.1395C>A p.I465= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV53239931; called by muse, mutect2, varscan2
- H2BC11 | c.300C>T p.R100= | Silent (SNP) | VAF 60/103 reads (58%) | catalogued as rs1024478626, COSV60362570; called by muse, mutect2, varscan2
- HAVCR2 | c.102C>T p.A34= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs1163489376, COSV57154352; called by muse, mutect2, varscan2
- HLCS | c.2136C>T p.N712= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99293141; called by mutect2, varscan2
- HTR1A | c.666G>C p.A222= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV60500938, COSV60502320; called by muse, mutect2, varscan2
- IGSF10 | c.3318C>A p.V1106= | Silent (SNP) | VAF 32/229 reads (14%) | catalogued as rs760102847, COSV56790141; called by muse, mutect2, varscan2
- LRP2 | c.9591C>T p.I3197= | Silent (SNP) | VAF 39/180 reads (22%) | catalogued as rs775516231, COSV55567904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MORC1 | c.1803C>T p.G601= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs767341013, COSV51715855, COSV51723547; called by mutect2, varscan2
- MUC17 | c.810T>A p.P270= | Silent (SNP) | VAF 63/198 reads (32%) | catalogued as rs1451200961, COSV60299122; called by muse, mutect2, varscan2
- NCAN | c.1449C>T p.F483= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV53056235; called by muse, mutect2, varscan2
- NPAP1 | c.157C>A p.R53= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs748668348, COSV61508752, COSV61510074; called by muse, mutect2, varscan2
- OR4D5 | c.771C>A p.V257= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV58306609, COSV58308848; called by muse, mutect2, varscan2
- OR4L1 | c.24A>G p.L8= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV59850905; called by muse, mutect2, varscan2
- PCDHB6 | c.2124G>C p.A708= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs375622168, COSV50689541; called by muse, mutect2, varscan2
- PCDHGA10 | c.1794G>A p.V598= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs764972439, COSV54006092; called by muse, mutect2, varscan2
- PCDHGA6 | c.2406A>T p.G802= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV54006073; called by muse, mutect2, varscan2
- PCDHGB4 | c.2199C>T p.S733= | Silent (SNP) | VAF 47/175 reads (27%) | catalogued as COSV53919516; called by muse, mutect2, varscan2
- PKD1L1 | c.978C>T p.F326= | Silent (SNP) | VAF 71/230 reads (31%) | catalogued as rs142684649, COSV56958530; called by muse, mutect2, varscan2
- PKHD1L1 | c.4977A>G p.P1659= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV65749909; called by muse, mutect2, varscan2
- PLCH1 | c.2724A>G p.V908= (on ENST00000340059 / NM_001130960.2; = p.V900= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as COSV58207260, COSV58207311; called by muse, mutect2, varscan2
- PLD1 | c.3126A>G p.G1042= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV60572584; called by muse, mutect2, varscan2
- POLR3B | c.2793A>C p.P931= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV57283070; called by muse, mutect2, varscan2
- PRKG1 | c.1890G>A p.K630= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV64775712; called by muse, mutect2, varscan2
- RTP5 | c.948C>G p.V316= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV58321365; called by muse, mutect2, varscan2
- SLC16A7 | c.999G>C p.L333= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV53898264, COSV99676736; called by muse, mutect2, varscan2
- SLC5A5 | c.285T>A p.L95= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV55834799; called by muse, mutect2, varscan2
- SLC6A3 | c.471C>T p.N157= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs755940757, COSV54368152; called by muse, mutect2, varscan2
- SLITRK3 | c.2625G>T p.G875= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99579081; called by muse, mutect2, varscan2
- SRRM2 | c.6051C>T p.R2017= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV51941594; called by muse, mutect2, varscan2
- TBC1D9 | c.480C>G p.L160= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV71308311; called by muse, mutect2, varscan2
- TET3 | c.2553G>T p.T851= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs759401050, COSV69644875; called by muse, mutect2, varscan2
- TMEM45B | c.30A>G p.P10= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs761129494, COSV55654923; called by muse, mutect2, varscan2
- TOMM20 | c.45C>T p.A15= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as COSV64013231; called by muse, mutect2, varscan2
- VNN2 | c.1527A>G p.L509= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs774294453, COSV58473788; called by muse, mutect2, varscan2
- XIRP2 | c.276G>T p.R92= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV54724787; called by muse, mutect2, varscan2
- ZCCHC12 | c.477T>A p.A159= | Silent (SNP) | VAF 93/223 reads (42%) | catalogued as COSV59572606; called by muse, mutect2, varscan2
- ZCCHC2 | c.1380C>T p.S460= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV54040217; called by muse, mutect2, varscan2
- ZFYVE9 | c.780G>A p.A260= | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as rs149478229; called by muse, mutect2, varscan2
- ZNF513 | c.117A>G p.L39= | Silent (SNP) | VAF 54/168 reads (32%) | catalogued as COSV52009657; called by muse, mutect2, varscan2
- AC244258.1 | n.995G>T | RNA (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- CAMKK1 | c.685+205G>T | Intron (SNP) | VAF 23/42 reads (55%) | catalogued as rs915095952, COSV99340235; called by muse, mutect2, varscan2
- HERC2P3 | n.494G>T | RNA (SNP) | VAF 9/31 reads (29%) | catalogued as rs1203339480; called by muse, mutect2, varscan2
- MIR518D | n.58C>T | RNA (SNP) | VAF 17/99 reads (17%) | catalogued as rs768503953; called by muse, mutect2, varscan2
- MYBPC1 | c.3413-1738C>A | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100637928; called by muse, mutect2, varscan2
- TOX2 | c.907-933C>A | Intron (SNP) | VAF 52/183 reads (28%) | catalogued as COSV100363759; called by muse, mutect2, varscan2
